Somatic mutation profile of tumor specimen TCGA-HM-A6W2-01A (aliquot TCGA-HM-A6W2-01A-21D-A33O-09) from TCGA case TCGA-HM-A6W2, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 35.0 years (12,775 days).
Specimen TCGA-HM-A6W2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 835a5382-f43e-4ca4-90f3-c608843362a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HM-A6W2-10A (Blood Derived Normal), aliquot TCGA-HM-A6W2-10A-01D-A33O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a77d524f-9d96-4846-86cf-871dfb35d6d9

The open-access MAF lists 58 somatic variants for this specimen: 36 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 21, Nonsense Mutation 3, Intron 1, In Frame Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 23/26 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BAHCC1 | c.5700G>A p.A1900= | Splice Region (SNP) | VAF 17/42 reads (40%) | catalogued as rs372194536; called by muse, mutect2, varscan2
- CHIC2 | c.412A>C p.K138Q | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99816202; called by muse, mutect2, varscan2
- DCLRE1C | c.37A>C p.T13P | Missense Mutation (SNP) | VAF 109/259 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as COSV100739967; called by muse, mutect2, varscan2
- EEA1 | c.1200_1202del p.Q401del | In Frame Del (DEL) | VAF 52/115 reads (45%) | catalogued as rs766291127; called by pindel, varscan2
- ERCC6L2 | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 24/88 reads (27%) | catalogued as rs779856407, COSV99998968; called by muse, mutect2, varscan2
- GAS8 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs770183431, COSV99244187; called by muse, mutect2, varscan2
- GJB4 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.394); catalogued as rs185327282; called by muse, mutect2, varscan2
- GNAL | c.547-2A>T p.X183_splice (on ENST00000269162 / NM_001142339.3; = p.X260_splice on NM_182978.4) | Splice Site (SNP) | VAF 21/59 reads (36%) | catalogued as COSV99303666; called by muse, mutect2, varscan2
- GRM6 | c.1390G>A p.G464R | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748724069, COSV99179648; called by muse, mutect2, varscan2
- HSPA12A | c.802G>A p.G268S | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs781929997, COSV65023664; called by muse, mutect2, varscan2
- IGSF1 | c.1444T>A p.Y482N | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100812289; called by muse, mutect2, varscan2
- IVNS1ABP | c.694C>T p.L232F | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.383); catalogued as COSV100832569; called by muse, mutect2, varscan2
- KDM6A | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV100938552; called by muse, mutect2, varscan2
- LCT | c.5657T>G p.V1886G | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV99739566; called by muse, mutect2, varscan2
- MACC1 | c.342T>A p.D114E | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.214); catalogued as COSV100256245, COSV100256313; called by muse, mutect2, varscan2
- MAGEB2 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV100975744; called by muse, mutect2, varscan2
- MARCHF11 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1383446854, COSV100197580, COSV60131250; called by muse, mutect2, varscan2
- MOB3A | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100830073; called by muse, mutect2, varscan2
- MYORG | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1176622569, COSV52628998; called by muse, mutect2, varscan2
- NDUFS1 | c.1810C>T p.Q604* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV99261041; called by muse, mutect2, varscan2
- NLRP11 | c.2441G>A p.R814H | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV64085555; called by muse, mutect2, varscan2
- PAPSS2 | c.1052C>A p.T351K | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100753675; called by muse, mutect2, varscan2
- PARD6G | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV100783468; called by muse, mutect2, varscan2
- PCDHA13 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); catalogued as COSV56487670; called by muse, mutect2, varscan2
- PKP4 | c.2618G>T p.G873V | Missense Mutation (SNP) | VAF 87/225 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100733973; called by muse, mutect2, varscan2
- PLCB4 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.854); catalogued as rs144345083; ClinVar: benign; called by muse, mutect2, varscan2
- PRDM2 | c.3127G>T p.A1043S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.223); catalogued as COSV52445067; called by muse, mutect2
- PSMB5 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs770354735, COSV100557409; called by muse, mutect2, varscan2
- RTEL1 | c.130A>G p.T44A | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100542412; called by muse, mutect2, varscan2
- SBNO1 | c.3905G>A p.R1302H (on ENST00000420886; = p.R1301H on NM_018183.5) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV57347449; called by muse, mutect2, varscan2
- SPEN | c.5908G>T p.E1970* | Nonsense Mutation (SNP) | VAF 41/120 reads (34%) | catalogued as COSV101005556, COSV65368949; called by muse, mutect2, varscan2
- SYCP1 | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101050980, COSV65696175; called by muse, mutect2, varscan2
- TGM4 | c.1913G>A p.G638E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV56096952; called by muse, mutect2
- ZNF99 | c.2086A>C p.K696Q | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.719); catalogued as rs575181311, COSV101233951; called by muse, mutect2, varscan2
- ZRANB3 | c.1852C>A p.P618T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99924616, COSV99925011; called by muse, mutect2, varscan2
- ARHGEF10L | c.1681C>A p.R561= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV99393747; called by muse, mutect2, varscan2
- CGNL1 | c.1419C>A p.T473= | Silent (SNP) | VAF 29/44 reads (66%) | catalogued as COSV55572876, COSV99849072; called by muse, mutect2, varscan2
- COL11A1 | c.879G>A p.E293= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs749538662, COSV100616929; called by muse, mutect2, varscan2
- CYLC1 | c.1689C>T p.G563= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV100254785; called by muse, mutect2, varscan2
- DCAF5 | c.1221G>A p.Q407= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as rs1024584172, COSV100432566; called by muse, mutect2, varscan2
- DIDO1 | c.2478A>T p.T826= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99826998; called by muse, mutect2, varscan2
- E2F8 | c.337C>A p.R113= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV100001702, COSV51463044; called by muse, mutect2, varscan2
- HSPBP1 | c.873C>T p.H291= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs1013095423, COSV99729101; called by muse, mutect2, varscan2
- KL | c.2469A>G p.K823= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV101199193; called by muse, mutect2, varscan2
- LDLRAD4 | c.162G>T p.P54= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV100762732, COSV63340382; called by muse, mutect2, varscan2
- MACF1 | c.20784T>C p.T6928= (on ENST00000372915; = p.T4973= on NM_012090.5) | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV99244908; called by muse, mutect2, varscan2
- MIB2 | c.1632C>T p.D544= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100598940; called by muse, mutect2, varscan2
- MNAT1 | c.61C>T p.L21= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as rs141089655, COSV99710400; called by muse, mutect2, varscan2
- PARD6B | c.354C>T p.N118= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as rs767606667, COSV65404275; called by muse, mutect2, varscan2
- PKHD1L1 | c.2754C>G p.G918= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as COSV101006763; called by muse, mutect2, varscan2
- PODN | c.1779G>A p.T593= (on ENST00000395871; = p.T545= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as rs547822345, COSV57011524; called by muse, mutect2, varscan2
- PRKD2 | c.2178G>A p.Q726= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV99354620; called by muse, mutect2, varscan2
- SLIT2 | c.954A>T p.G318= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV99884446; called by muse, mutect2, varscan2
- TJP3 | c.2415C>T p.S805= | Silent (SNP) | VAF 70/172 reads (41%) | catalogued as rs1412261409, COSV99516443; called by muse, mutect2
- TSC2 | c.1917G>T p.R639= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as COSV99555213; called by muse, mutect2, varscan2
- TUBA1C | c.984C>T p.V328= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV99988823; called by muse, mutect2, varscan2
- TTN | c.34264+5521G>T | Intron (SNP) | VAF 31/70 reads (44%) | catalogued as COSV100616651, COSV60293460; called by muse, mutect2, varscan2
